TCGA case TCGA-KC-A7FA — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: Cornell Medical College. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3f3128c9-1072-443c-b6ae-8b63166fa9a4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 63.5 years (23,208 days); Year of diagnosis: 2013; Method of diagnosis: Core Biopsy; AJCC clinical T: T2c; AJCC clinical M: M0; AJCC pathologic T: T3a; AJCC pathologic N: N0; Primary gleason grade: Pattern 3; Secondary gleason grade: Pattern 4; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Gleason score: 7.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 24; Tumor level prostate: Apex / Middle / Base; Zone of origin prostate: Peripheral zone.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Papillary transitional cell carcinoma: ICD-O-3 morphology code: 8130/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 60.6 years (22,142 days); Days to diagnosis: -1,066 days (-2.9 years); AJCC staging edition: 7th; AJCC pathologic T: Ta; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage 0a.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,066 days (-2.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (4 entries)
- Day 40 (initial diagnosis): Days to imaging: 40 days; Imaging type: MRI; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 62 (initial diagnosis): Days to imaging: 62 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 70 (initial diagnosis): Days to imaging: 70 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Days to follow up: 598 days (1.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 0 ng/mL (day 161).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KC-A7FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 120 mg.
  Slide TCGA-KC-A7FA-01A-02-TSB: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KC-A7FA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Method initial path diagnosis: Core needle biopsy; Bone scan results: Abnormal (not related to prostate cancer); Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Treatment outcome first course: Complete Remission/Response; Biochemical recurrence indicator: No; New tumor event diagnosis indicator: No.
- Tumor levels: Tumor level: Apex; Tumor level: Middle; Tumor level: Base.
- Stage record, Psa: PSA most recent results: 0.00.
- Stage record, Gleason grading: Gleason pattern primary: 3; Gleason pattern secondary: 4.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder; Other malignancy histological type: Low Grade Papillary Urothelial Carcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Transurethral resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 598 days; disease-specific survival: no event (censored), 598 days; disease-free interval: no event (censored), 598 days; progression-free interval: no event (censored), 598 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KC-A7FA-01A-21D-A33S-01): tumor purity 0.74, ploidy 1.93, whole-genome doublings 0.
